Gene-level copy-number profile of tumor specimen C3N-01517-01 from CPTAC case C3N-01517, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 49.9 years (18,211 days).
Specimen C3N-01517-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 036f64ce-e92a-4c84-bafa-8edc8a84547d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-01517-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/f26f9909-7040-4715-94e6-e0004e0078d1

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 130; copy number 1: 43; copy number 2: 6,272; copy number 3: 1,560; copy number 4: 43,400; copy number 5: 1,552; copy number 6: 5,925; copy number 7: 5; copy number 8: 10; copy number 15: 1; copy number 139: 7; copy number 143: 8.

Homozygous deletions (total copy number 0; autosomes only): 128 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,789,179–19,895,973, 2 genes: AL158077.2, AL158077.1.
- chr9:20,331,446–27,610,745, 110 genes (broad region; genes not listed).
- chr9:27,937,617–29,826,711, 11 genes: AL353746.1, LINGO2, AL451124.1, AL445526.1, KCTD10P1, MIR876, MIR873, AL162388.1, AL353684.1, AL354676.1, ME2P1.
- chr9:32,727,069–32,869,595, 5 genes: AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 16 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:54,542,325–55,433,742, 15 genes, copy number 139–143: VSTM2A, VSTM2A-OT1, AC011228.1, RNU6-1125P, RPL31P35, SEC61G, SEC61G-DT, AC006971.1, EGFR, EGFR-AS1, ELDR, AC073324.1, CALM1P2, AC073347.1, LANCL2.
- chr9:67,512,034–67,515,393, 1 gene, copy number 15: BX664730.1.

Autosomal genes at a single copy (total copy number 1): 33. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
